Gene-level copy-number profile of tumor specimen TCGA-SI-A71O-01A from TCGA case TCGA-SI-A71O, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 29.3 years (10,710 days).
Specimen TCGA-SI-A71O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.f688fae7-a29c-4e17-9f9f-57c6bb09b305.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SI-A71O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/add989e0-402e-4f7f-a559-57408cead6bb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 982; copy number 2: 13,786; copy number 3: 20,071; copy number 4: 17,040; copy number 5: 4,984; copy number 6: 1,791; copy number 7: 433; copy number 8: 720.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SI-A71O-01A-12D-A33D-01): tumor purity 0.94, ploidy 1.59, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:208,266,255–208,358,746, 1 gene (within-gene range 0–2): PIKFYVE.
- chr13:48,296,162–48,303,661, 1 gene: RB1-DT.
- chr13:48,316,863–48,328,564, 2 genes: PPP1R26P1, PCNPP5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,153 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–896,435, 23 genes, copy number 8 (within-gene range 5–8): AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1.
- chr7:19,353,531–19,818,090, 5 genes, copy number 7 (within-gene range 6–7): AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1.
- chr7:64,612,535–65,401,136, 35 genes, copy number 8: AC016769.5, AC016769.6, ZNF107, BNIP3P11, MIR6839, AC091799.1, AC073349.3, ZNF138, AC073349.4, AC073349.2, SEPHS1P1, EEF1DP4, AC073349.5, ZNF273, AC073349.1, VN1R42P, MTDHP1, AC073210.3, ZNF117, ERV3-1, RNU6-1229P, CCT6P3, AC073210.2, SNORA22C, SNORA15B-1, AC073210.1, GTF2IP14, INTS4P1, AC104073.2, AC104073.1, AC104073.4, AC104073.3, RSL24D1P3, AC092685.1, ZNF92.
- chr8:114,791,653–120,445,402, 54 genes, copy number 8 (within-gene range 6–8): CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13.
- chr8:143,684,452–145,066,685, 99 genes, copy number 7 (broad region; genes not listed).
- chr13:113,149,432–114,337,626, 44 genes, copy number 7: AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:28,264,390–28,613,623, 5 genes, copy number 7: BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12.
- chr19:3,224,661–17,788,568, 786 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr19:27,793,431–27,984,984, 1 gene, copy number 7 (within-gene range 6–7): AC006504.5.
- chr19:27,849,635–28,125,430, 7 genes, copy number 7: AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr19:33,906,352–33,927,625, 2 genes, copy number 7: AC008556.1, RN7SL150P.
- chr20:4,059,633–9,481,242, 84 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:11,800,463–12,381,255, 8 genes, copy number 7: LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.

Autosomal genes at a single copy (total copy number 1): 437. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
